Somatic mutation profile of tumor specimen TCGA-2Y-A9H7-01A (aliquot TCGA-2Y-A9H7-01A-11D-A38X-10) from TCGA case TCGA-2Y-A9H7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 81.5 years (29,752 days).
Specimen TCGA-2Y-A9H7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c179a732-3131-443c-a068-832c8cf1dbe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H7-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H7-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca0d246d-ef57-4eaa-833b-2fe32b96208b

The open-access MAF lists 81 somatic variants for this specimen: 66 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 59, Silent 15, Frame Shift Del 3, Nonsense Mutation 2, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SPTA1 | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918634, CM890108, COSV100934803; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALKBH4 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99479301; called by muse, mutect2, varscan2
- ALKBH4 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99479304; called by muse, mutect2, varscan2
- AMPH | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.997); catalogued as COSV100341855, COSV57750213; called by muse, mutect2, varscan2
- ARHGAP22 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1309338429, COSV50942192; called by muse, mutect2, varscan2
- ASXL1 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100038917; called by muse, mutect2, varscan2
- ATP2A2 | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100428581; called by muse, mutect2
- ATP6V0A1 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV99230885; called by muse, mutect2, varscan2
- AXIN1 | c.878+1G>C p.X293_splice | Splice Site (SNP) | VAF 17/18 reads (94%) | catalogued as COSV51994447, COSV99249719; called by muse, mutect2, varscan2
- BAZ2B | c.1343C>G p.S448W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.563); catalogued as COSV100600587; called by muse, mutect2, varscan2
- BRAP | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100554104; called by muse, mutect2, varscan2
- C15orf39 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100641316; called by muse, mutect2, varscan2
- C16orf86 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV99708183; called by muse, mutect2, varscan2
- CCDC122 | c.767A>T p.Q256L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as COSV101480971; called by muse, mutect2, varscan2
- CCDC141 | c.3107G>A p.G1036E | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV55371199, COSV55373032, COSV55376755; called by muse, mutect2, varscan2
- CHAT | c.2068C>A p.L690I | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.075); catalogued as COSV100340070, COSV60323258; called by muse, mutect2, varscan2
- CIZ1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99476819; called by muse, mutect2, varscan2
- COQ2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 221/450 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1221771114, COSV100269975; called by muse, mutect2, varscan2
- CTDP1 | c.1381A>T p.S461C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99310490; called by muse, mutect2, varscan2
- DNAH2 | c.10747G>A p.A3583T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV101209254; called by muse, varscan2
- DNM3 | c.2300G>T p.R767L (on ENST00000355305 / NM_001350206.2; = p.R761L on NM_015569.5) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.088); catalogued as COSV100798099, COSV100798567; called by muse, mutect2, varscan2
- EFCAB5 | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.287); catalogued as rs1442815981, COSV100300182; called by muse, mutect2, varscan2
- EPOR | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV99710125; called by muse, mutect2, varscan2
- ESR2 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as rs141940742, COSV50837747; called by muse, mutect2, varscan2
- FAN1 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100755951; called by muse, mutect2, varscan2
- FAT1 | c.13766G>T p.*4589Lext*94 | Nonstop Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101499313; called by muse, mutect2
- FBN3 | c.5552G>C p.C1851S | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99560797; called by muse, mutect2, varscan2
- FOXP4 | c.1373A>G p.H458R (on ENST00000307972 / NM_001012426.1; = p.H445R on NM_138457.3) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100332666; called by muse, mutect2, varscan2
- FXR1 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.811); catalogued as COSV99976347; called by muse, mutect2, varscan2
- HDAC11 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs753220024, COSV99849882; called by muse, mutect2, varscan2
- HSDL2 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV99356790; called by muse, mutect2, varscan2
- KCNH6 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs560791257, COSV59006932; called by muse, mutect2, varscan2
- LRP2 | c.8306G>C p.G2769A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV99788131; called by muse, mutect2, varscan2
- MAST2 | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs368958391, COSV100788750; called by muse, mutect2, varscan2
- NETO1 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs778182466, COSV55001979; called by muse, mutect2, varscan2
- NFASC | c.33T>G p.H11Q | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.429); catalogued as COSV100363670; called by muse, mutect2, varscan2
- NKX3-1 | c.685T>A p.W229R | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101082760; called by muse, mutect2, varscan2
- NPFFR2 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV100440632; called by muse, mutect2, varscan2
- OGG1 | c.995T>A p.L332H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99844727; called by muse, mutect2, varscan2
- OR2A4 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100199668; called by muse, varscan2
- OR2T6 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 90/158 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as COSV100861549, COSV63216628; called by muse, mutect2, varscan2
- PLEKHA1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs746534987, COSV100935484; called by muse, mutect2, varscan2
- PPP1R36 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100072833; called by muse, mutect2, varscan2
- PSG1 | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99739800, COSV99742066; called by muse, mutect2, varscan2
- SEC23A | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV56977343; called by muse, mutect2, varscan2
- SELENBP1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs544356174, COSV64374269; called by muse, mutect2, varscan2
- SLC35G5 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as rs754026343, COSV99644231; called by muse, mutect2, varscan2
- SLC39A12 | c.1009A>T p.S337C | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.159); catalogued as COSV101070046; called by muse, mutect2, varscan2
- SLC8A1 | c.2269G>T p.G757W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100245771; called by muse, mutect2, varscan2
- SPON1 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs996546516, COSV100115753; called by muse, mutect2, varscan2
- SRSF3 | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59670741; called by muse, mutect2, varscan2
- STUB1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs145094142; called by muse, mutect2, varscan2
- THUMPD3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1413101507, COSV100560623; called by muse, mutect2, varscan2
- TIMM50 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100067905; called by muse, mutect2, varscan2
- TREML1 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.296); catalogued as COSV100632593; called by muse, mutect2, varscan2
- TRPV5 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1282109797, COSV54689262; called by muse, mutect2, varscan2
- UEVLD | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100293146; called by muse, mutect2, varscan2
- VPS36 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as COSV100955185; called by muse, mutect2, varscan2
- ZC3H14 | c.424A>G p.N142D | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as COSV99193029; called by muse, mutect2, varscan2
- ZDHHC23 | c.598A>T p.S200C | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100362126; called by muse, mutect2, varscan2
- ZFYVE26 | c.1772C>G p.P591R | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); catalogued as COSV100720365; called by muse, mutect2, varscan2
- ZNF394 | c.214T>G p.Y72D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100460152; called by muse, mutect2, varscan2
- IRF7 | c.1207del p.S403Pfs*62 (on ENST00000397566; = p.S390Pfs*62 on NM_001572.5) | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, pindel, varscan2
- ISYNA1 | c.374_375del p.A125Gfs*92 | Frame Shift Del (DEL) | VAF 45/130 reads (35%) | called by pindel, varscan2
- PCSK7 | c.1734_1741delinsC p.C579Gfs*30 | Frame Shift Del (DEL) | VAF 88/687 reads (13%) | called by pindel, varscan2*
- CNIH4 | c.321G>A p.L107= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV100837001; called by muse, mutect2, varscan2
- DOCK3 | c.2205G>A p.K735= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV99811435; called by muse, mutect2, varscan2
- ELMOD3 | c.162G>A p.Q54= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs781711502, COSV100226248; called by muse, mutect2, varscan2
- FAT1 | c.270C>T p.L90= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs373265178; called by muse, mutect2, varscan2
- ITPR2 | c.942A>G p.L314= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV101189959; called by muse, mutect2, varscan2
- LGR4 | c.2529C>T p.Y843= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs145204350; called by muse, mutect2, varscan2
- NTAQ1 | c.436C>A p.R146= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99783606; called by muse, mutect2, varscan2
- PKD1 | c.11701C>T p.L3901= (on ENST00000262304 / NM_001009944.3; = p.L3900= on NM_000296.4) | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV99237995; called by muse, mutect2, varscan2
- RYR2 | c.12678G>A p.P4226= | Silent (SNP) | VAF 93/171 reads (54%) | catalogued as rs768348987, COSV63663009; called by muse, mutect2, varscan2
- SNCB | c.36G>A p.K12= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as COSV100031240; called by muse, mutect2, varscan2
- SPEN | c.10062T>G p.P3354= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100999008; called by muse, mutect2, varscan2
- TAOK1 | c.72A>C p.P24= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99913960; called by muse, mutect2, varscan2
- ZFP2 | c.678C>T p.S226= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV100797045; called by muse, mutect2, varscan2
- ZNF214 | c.543A>G p.E181= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99547358; called by muse, mutect2, varscan2
- ZNF592 | c.189G>T p.V63= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100245836; called by muse, mutect2, varscan2
